Somatic mutation profile of tumor specimen C3N-02716-03 (aliquot CPT0177390006) from CPTAC case C3N-02716, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 76.9 years (28,077 days).
Specimen C3N-02716-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45a55f9b-08b1-46f2-be86-cee685e21cb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02716-71 (Blood Derived Normal), aliquot CPT0177460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3f076e2-bba7-4c44-95e6-b64ae8f35108

The open-access MAF lists 1,533 somatic variants for this specimen: 876 protein-altering or splice-affecting, 463 silent, 194 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 784, Silent 463, Intron 96, Nonsense Mutation 49, 5'UTR 26, RNA 25, Splice Region 23, 3'UTR 20, 5'Flank 18, Splice Site 17, 3'Flank 9, Frame Shift Del 2.

Variants (750 of 1,533; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNC | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 60/563 reads (11%) | catalogued as rs1562998062, COSV57965369; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 87/438 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 47/473 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs120074183, CM144634, CM1511176, CM960905, COSV50101145; ClinVar: pathogenic / not provided; called by muse, mutect2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 46/311 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 43/365 reads (12%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 18/192 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs587781371, CD136796, COSV52684761, COSV53551526; ClinVar: uncertain significance; called by muse, mutect2
- AATK | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as rs1180126746; called by muse, mutect2, varscan2
- ABCA3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM152710; called by muse, mutect2, varscan2
- ABCA7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as CM157252; called by muse, mutect2, varscan2
- AC011462.1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 58/642 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54199597; called by muse, mutect2
- ACAN | c.5135G>A p.G1712E | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs760776040, COSV61358864; called by muse, mutect2, varscan2
- ADAMTS4 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs113816084; called by muse, mutect2
- ADAMTSL3 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 47/574 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs762061262, COSV54435420; called by muse, mutect2
- ADGRG1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 67/549 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs776480483, COSV65635964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs780577841; called by muse, mutect2
- AK7 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV50885726; called by muse, mutect2, varscan2
- AKAP12 | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs753184741; called by muse, mutect2, varscan2
- ALG12 | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 48/393 reads (12%) | PolyPhen benign (0.025); catalogued as rs746468248; called by muse, mutect2, varscan2
- ALOX5 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184151327, COSV65555095; called by muse, mutect2
- ALPK2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs754851733, COSV64493614; called by muse, mutect2, varscan2
- ALPK3 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 18/255 reads (7%) | catalogued as rs1344615174, COSV51939552; called by muse, mutect2
- AMDHD1 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372245131, COSV57140703, COSV99900400; called by muse, mutect2
- AMPH | c.1154G>A p.W385* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs866753134, COSV57740661; called by muse, varscan2
- ANGEL1 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51873700; called by muse, mutect2, varscan2
- ANHX | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1271810788; called by muse, mutect2
- ANO5 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs926233739, COSV61081781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP002512.3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99688122; called by muse, mutect2
- ARHGAP36 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.641); catalogued as COSV52268480; called by muse, mutect2, varscan2
- ARRDC2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 52/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260688515; called by muse, mutect2
- ASXL3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99324027, COSV99326364; called by muse, mutect2, varscan2
- ASXL3 | c.5827C>T p.P1943S | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs1323570694, COSV52462827; called by muse, mutect2, varscan2
- ATG16L1 | c.1448G>A p.R483Q (on ENST00000392017 / NM_030803.7; = p.R464Q on NM_017974.4) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1388588234; called by muse, mutect2
- B3GAT1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 51/441 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs1260573814, COSV57000498; called by muse, mutect2, varscan2
- BACE2 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV57739721; called by muse, mutect2
- BAIAP2L2 | c.1259+1G>A p.X420_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as rs1417020063; called by muse, mutect2
- BAZ2A | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1409374854; called by muse, mutect2, varscan2
- BCL11A | c.1813G>A p.E605K (on ENST00000335712 / NM_001365609.1; = p.E639K on NM_018014.4) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs865852690; called by muse, mutect2, varscan2
- BCL11B | c.1456G>A p.G486S (on ENST00000357195 / NM_001282237.2; = p.G415S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/579 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs1467652082; called by muse, mutect2, varscan2
- BEND7 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs139297820; called by muse, mutect2, varscan2
- BICRA | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV67606558; called by muse, mutect2, varscan2
- BRINP1 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs867591425, COSV56298072; called by muse, mutect2, varscan2
- BUB1B | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs754970139; called by muse, mutect2, varscan2
- C8B | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs772116036, COSV64779730; called by muse, mutect2
- CA11 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50033615; called by muse, mutect2
- CACNA1A | c.2630G>A p.G877D | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1326232769; called by muse, mutect2, varscan2
- CACNA1B | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as rs768464282; called by muse, mutect2
- CADPS2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753686489, COSV57361028; called by muse, mutect2, varscan2
- CAPN13 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs757990075; called by muse, mutect2, varscan2
- CAPN15 | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1376177778; called by muse, mutect2, varscan2
- CASP8 | c.1081del p.Q361Rfs*21 (on ENST00000432109 / NM_033355.3; = p.Q378Rfs*21 on NM_001228.4) | Frame Shift Del (DEL) | VAF 28/238 reads (12%) | catalogued as COSV51855642; called by pindel, varscan2
- CBLIF | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1475314626; called by muse, mutect2
- CBY2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772983757; called by muse, mutect2
- CCDC57 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV66439006; called by muse, mutect2, varscan2
- CCDC70 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99665349; called by muse, mutect2
- CD164 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1363450599; called by muse, mutect2
- CDH19 | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as COSV50954246; called by muse, mutect2
- CDH23 | c.7382C>T p.S2461F | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs373823262; called by muse, mutect2
- CDHR1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 44/312 reads (14%) | catalogued as CM153052, COSV60564251; called by muse, mutect2, varscan2
- CENPB | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs1299814146; called by muse, mutect2, varscan2
- CERS2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs759901901, COSV54989212; called by muse, mutect2, varscan2
- CES2 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57696431; called by muse, mutect2
- CFAP298-TCP10L | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs759080022; called by muse, mutect2, varscan2
- CFAP92 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV54046845; called by muse, mutect2, varscan2
- CFHR5 | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1169580920; called by muse, mutect2
- CHRNA7 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 82/1469 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs757687293; called by muse, mutect2
- CHST13 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs750870511; called by muse, mutect2
- CLCNKB | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 37/321 reads (12%) | catalogued as rs778485688, CM108309; called by muse, mutect2, varscan2
- CNOT7 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1390932291; called by muse, mutect2, varscan2
- CNTNAP4 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV56698027, COSV56705357; called by muse, mutect2
- COL10A1 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548773444; called by muse, mutect2
- COL11A1 | c.3827G>A p.G1276E | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62173050, COSV62193566; called by muse, mutect2, varscan2
- COL17A1 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as rs1393551909, COSV62229401; called by muse, mutect2
- COL1A2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 58/636 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51957974; called by muse, mutect2
- COL23A1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 43/494 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.258); catalogued as rs371407481; called by muse, mutect2
- COL2A1 | c.3920C>T p.T1307I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.315); catalogued as rs761461081; called by muse, mutect2, varscan2
- COL5A3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs372965257; called by muse, mutect2, varscan2
- CPS1 | c.3947C>T p.P1316L | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs758481966; called by muse, mutect2
- CRISP3 | c.169C>T p.P57S (on ENST00000371159 / NM_001368123.1; = p.P39S on NM_006061.4) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV53820702; called by muse, mutect2, varscan2
- CRY1 | c.1587T>C p.S529= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as COSV50481993; called by muse, mutect2, varscan2
- CSF2RA | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs746550319; called by muse, mutect2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2
- CSMD1 | c.2491G>C p.G831R (on ENST00000520002; = p.G830R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59284241; called by muse, mutect2
- CSMD3 | c.4781G>A p.G1594E (on ENST00000297405 / NM_001363185.1; = p.G1490E on NM_052900.3) | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV52192913, COSV52193853; called by muse, mutect2
- CSNK1A1L | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1222989617, COSV65789834; called by muse, mutect2, varscan2
- CSNK1E | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs778628868; called by muse, mutect2
- CSNK2A3 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 23/327 reads (7%) | catalogued as rs759040823; called by muse, mutect2
- CYP1A2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 62/558 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs781680722; called by muse, mutect2, varscan2
- CYP2C9 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.503); catalogued as COSV99582233; called by muse, mutect2, varscan2
- CYRIA | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV62863601, COSV62867345; called by muse, mutect2
- DAG1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 28/274 reads (10%) | catalogued as COSV58185276; called by muse, mutect2
- DDX18 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs781521649, COSV54310051; called by muse, mutect2, varscan2
- DGAT2 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930059; called by muse, mutect2
- DHX16 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64565636; called by muse, mutect2, varscan2
- DHX34 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866935357, COSV60895503; called by muse, mutect2
- DHX58 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV52428224; called by muse, mutect2, varscan2
- DIP2C | c.3169G>A p.V1057I | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.206); catalogued as rs1016127296, COSV55181632; called by muse, mutect2, varscan2
- DIS3 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV66705666; called by muse, mutect2, varscan2
- DNAAF1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 48/488 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57576404; called by muse, mutect2
- DNAAF2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.637); catalogued as rs1165233490; called by muse, mutect2, varscan2
- DNAH12 | c.8087C>T p.P2696L (on ENST00000351747; = p.P3564L on NM_001366028.2) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288239576; called by muse, mutect2
- DNAH5 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as COSV54208094; called by muse, mutect2
- DNAH6 | c.10469C>T p.S3490F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs1037994635, COSV52882626; called by muse, mutect2, varscan2
- DNMT3L | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99533192; called by muse, mutect2, varscan2
- DOCK6 | c.2927G>A p.G976D | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs765974838; called by muse, mutect2, varscan2
- DPPA4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509498, COSV59511688; called by muse, mutect2
- DPPA4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509998; called by muse, mutect2
- DSCAM | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs267606133, COSV68025194; called by muse, mutect2, varscan2
- DSPP | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs1355843745, COSV56810235; called by muse, mutect2, varscan2
- DYSF | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV50281990; called by muse, mutect2, varscan2
- EEF2KMT | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 92/912 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.049); catalogued as rs1282225127; called by muse, mutect2
- EIF2S3B | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as rs1453449614; called by muse, mutect2, varscan2
- EIF4A2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV56215421, COSV56217101; called by muse, mutect2
- ELAC1 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs572840694; called by muse, mutect2, varscan2
- ENGASE | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs762111541, COSV56135016; called by muse, mutect2
- ENO4 | c.639G>A p.G213= (on ENST00000622726; = p.G212= on NM_001242699.2) | Splice Region (SNP) | VAF 4/31 reads (13%) | catalogued as rs1564846094; called by muse, mutect2, varscan2
- ERN1 | c.525G>A p.W175* | Nonsense Mutation (SNP) | VAF 32/284 reads (11%) | catalogued as rs1306164296; called by muse, mutect2, varscan2
- EXD1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as COSV59255234; called by muse, mutect2, varscan2
- EXOC3L1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145550510, COSV52047561; called by muse, mutect2, varscan2
- EXTL1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs547397854, COSV65332284; called by muse, mutect2
- EZHIP | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.902); catalogued as rs782359132; called by muse, mutect2, varscan2
- F2 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61318020; called by muse, mutect2, varscan2
- F8 | c.5561G>A p.W1854* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as CM010871, CM161995; called by muse, mutect2, varscan2
- FAM186B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs138346134; called by muse, mutect2, varscan2
- FASN | c.2683G>A p.V895M | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs376331574; called by muse, mutect2
- FAT1 | c.3706C>T p.L1236F | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71675861; called by muse, mutect2, varscan2
- FAT3 | c.13108G>A p.E4370K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV53077133; called by muse, mutect2, varscan2
- FBXW11 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV51608765; called by muse, mutect2
- FCRL2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV63835039; called by muse, mutect2
- FCRL3 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV63842497, COSV63845353; called by muse, mutect2
- FDXACB1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782760088, COSV99499428; called by muse, mutect2, varscan2
- FGD4 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.033); catalogued as rs1331279685; called by muse, mutect2, varscan2
- FGR | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV64969484; called by muse, mutect2, varscan2
- FLG | c.5891G>A p.R1964K | Missense Mutation (SNP) | VAF 76/726 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs762584607; called by muse, mutect2, varscan2
- FLG | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 44/550 reads (8%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.895); catalogued as rs771978807; called by muse, mutect2
- FMN2 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as COSV100146118; called by muse, mutect2
- FOXC1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1215019381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRAS1 | c.9169C>T p.P3057S | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV99348003; called by muse, varscan2
- FSD2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58008739; called by muse, mutect2
- GABRA2 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62917407; called by muse, mutect2
- GCK | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs556436603, CM015282, COSV60787999; ClinVar: uncertain significance; called by muse, mutect2
- GIMAP1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1439814461, COSV56188359; called by muse, mutect2, varscan2
- GIMAP4 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs756774213; called by muse, mutect2
- GIMAP8 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100217475; called by muse, varscan2
- GIPC3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.799); catalogued as rs927394211; called by muse, mutect2, varscan2
- GLI1 | c.3230C>T p.P1077L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57367549, COSV57367780; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 123/1826 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs755710594; called by muse, mutect2
- GPIHBP1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 37/378 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV100427401; called by muse, mutect2, varscan2
- GPR142 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.115); catalogued as rs758748746; called by muse, mutect2
- GPR149 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67668719; called by muse, mutect2, varscan2
- GPR17 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.037); catalogued as rs185075451; called by muse, mutect2, varscan2
- GPR65 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs139430517; called by muse, mutect2, varscan2
- GREM2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1390968124, COSV100547227, COSV58951193; called by muse, mutect2
- GRIA1 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as rs868448670; called by muse, mutect2, varscan2
- GRM8 | c.2705G>C p.S902T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.827); catalogued as COSV100281714; called by mutect2, varscan2
- GSTO2 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 35/306 reads (11%) | catalogued as rs371877418; called by muse, mutect2, varscan2
- GUSB | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 60/501 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV59220916; called by muse, mutect2, varscan2
- GYS1 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.885); catalogued as rs1345458151; called by muse, mutect2, varscan2
- HAP1 | c.1672G>A p.E558K (on ENST00000310778 / NM_001367460.1; = p.E506K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs782594738; called by muse, mutect2
- HLA-A | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV65136444, COSV65138215; called by muse, mutect2, varscan2
- HMCN2 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs781799175; called by muse, mutect2
- HNF1A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 87/725 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM020514; called by muse, mutect2, varscan2
- HORMAD2 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs772142712; called by muse, mutect2, varscan2
- HRG | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452094926; called by muse, mutect2
- HRH2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV51573466; called by muse, mutect2, varscan2
- HTR3B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867246724, COSV52744652; called by muse, mutect2
- HTR4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779822851, COSV58789696; called by muse, mutect2, varscan2
- HYI | c.418G>A p.G140R (on ENST00000372434 / NM_001330526.2; = p.G115R on NM_031207.6) | Missense Mutation (SNP) | VAF 63/620 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65095258; called by muse, mutect2, varscan2
- IBSP | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56895972; called by muse, mutect2
- IFT46 | c.186-5C>T | Splice Region (SNP) | VAF 14/117 reads (12%) | catalogued as rs781828935; called by muse, mutect2, varscan2
- IGLON5 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs552486209; called by muse, mutect2, varscan2
- IGSF1 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV63841373; called by muse, mutect2, varscan2
- IL23R | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as COSV61372604; called by muse, mutect2, varscan2
- INTS6L | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs782087250; called by muse, mutect2, varscan2
- ITGB4 | c.1455-1G>A p.X485_splice | Splice Site (SNP) | VAF 46/393 reads (12%) | catalogued as COSV52326603; called by muse, mutect2, varscan2
- ITGB4 | c.1455G>A p.W485* | Nonsense Mutation (SNP) | VAF 46/387 reads (12%) | catalogued as rs760385776; called by muse, mutect2, varscan2
- ITIH5 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150174865; called by muse, mutect2
- JADE3 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV54470550; called by muse, mutect2, varscan2
- JPH2 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 55/661 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778774256; called by muse, mutect2
- KBTBD11 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1211547979; called by muse, mutect2, varscan2
- KCNA6 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54975124; called by muse, mutect2, varscan2
- KCNH2 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV51214602; called by muse, mutect2
- KDR | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV55759764, COSV55765812; called by muse, mutect2
- KEL | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs778710806; called by muse, mutect2, varscan2
- KHDRBS2 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV55442939; called by muse, mutect2, varscan2
- KIAA1549 | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs1239505324; called by muse, mutect2, varscan2
- KIAA1549 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs764544349; called by muse, mutect2
- KIF2B | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV52132472; called by muse, mutect2, varscan2
- KIF2C | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767655510; called by muse, mutect2, varscan2
- KLC4 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs954346273; called by muse, mutect2
- KLHDC3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763609; called by muse, mutect2
- KRT4 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 48/542 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs758257972, COSV53406308; called by muse, mutect2
- KRTAP10-9 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 72/701 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100555919; called by muse, mutect2, varscan2
- LAMA2 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769731295, COSV70338717; called by muse, mutect2, varscan2
- LAMA5 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.892); catalogued as rs147301014; called by muse, mutect2, varscan2
- LCT | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768179301; called by muse, mutect2, varscan2
- LLGL2 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749188667; called by muse, mutect2
- MAGEC1 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV53569994; called by muse, mutect2
- MAPK8IP1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53797785; called by muse, mutect2, varscan2
- MARS1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV56255250; called by muse, mutect2, varscan2
- MARS2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779217180; called by muse, mutect2, varscan2
- MASP1 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs867948727, COSV61830451; called by muse, mutect2
- MASP1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 69/648 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV104401313; called by muse, mutect2, varscan2
- MAST3 | c.2582G>A p.G861D | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs778382790; called by muse, mutect2, varscan2
- MCF2L2 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as rs1420922248; called by muse, mutect2
- MCTP1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.188); catalogued as COSV100388215; called by muse, mutect2
- MFSD1 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as COSV99964031; called by muse, mutect2
- MGAM | c.4514G>A p.G1505E | Missense Mutation (SNP) | VAF 39/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527731; called by muse, mutect2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MGAT5B | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100047078; called by muse, mutect2
- MMP23B | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1284442187; called by muse, mutect2, varscan2
- MS4A4A | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.109); catalogued as COSV59700284; called by muse, mutect2, varscan2
- MTCH1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV65320126; called by muse, mutect2
- MUC16 | c.21725C>T p.S7242F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV67458459, COSV67472760; called by muse, mutect2, varscan2
- MUC16 | c.7457G>A p.G2486E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as rs1190521970; called by muse, mutect2
- MUC16 | c.7456G>A p.G2486R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs1255693645, COSV101199575, COSV101201840; called by muse, mutect2
- MUC22 | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.59); catalogued as COSV73736381; called by muse, mutect2
- MXRA5 | c.8044C>T p.P2682S | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs770177015, COSV54224243; called by muse, mutect2, varscan2
- MYH2 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 51/526 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55437861; called by muse, mutect2, varscan2
- MYH7B | c.5200G>A p.E1734K | Missense Mutation (SNP) | VAF 75/694 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs1363872742; called by muse, mutect2, varscan2
- MYO18B | c.7318G>A p.D2440N | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59125900; called by muse, mutect2, varscan2
- MYO3A | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755823253; called by mutect2, varscan2
- MYO3A | c.3997G>T p.E1333* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | catalogued as COSV56346416; called by muse, mutect2, varscan2
- MYO5C | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV55910340; called by muse, mutect2, varscan2
- MYO7B | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs535939017; called by muse, mutect2, varscan2
- MYOCD | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1051971711, COSV100591711; called by muse, mutect2
- NCALD | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99636355; called by muse, mutect2, varscan2
- NDUFS2 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV63487298; called by muse, mutect2
- NES | c.4407G>A p.W1469* | Nonsense Mutation (SNP) | VAF 40/364 reads (11%) | catalogued as COSV63962455; called by muse, mutect2
- NEXMIF | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV50032912, COSV99281438; called by muse, mutect2, varscan2
- NID2 | c.3743G>A p.W1248* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as rs1223301711; called by muse, mutect2
- NLRP7 | c.2875C>T p.P959S (on ENST00000340844 / NM_206828.3; = p.P988S on NM_139176.3) | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs953213546, COSV100051859; called by muse, mutect2
- NMUR2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200730009, COSV54918681; called by muse, mutect2
- NOTCH1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 78/784 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762151552, COSV53043280, COSV53047338; called by muse, mutect2
- NOTCH3 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs202228716; called by muse, mutect2, varscan2
- NPAP1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs865893523, COSV61507585; called by muse, mutect2
- NRK | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs770600883; called by mutect2, varscan2
- NRXN2 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775962047, COSV55461858; called by muse, mutect2, varscan2
- NT5C1A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV99348606; called by muse, mutect2
- NUDT21 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.446); catalogued as COSV100272956; called by muse, mutect2, varscan2
- NWD1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs145641467; called by muse, mutect2, varscan2
- OLFML3 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100233205; called by muse, mutect2, varscan2
- OPCML | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59409764, COSV59419626; called by muse, mutect2
- OPN4 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1436327654, COSV99618140; called by muse, mutect2, varscan2
- OR11G2 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV62132336; called by muse, mutect2
- OR4A15 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | catalogued as COSV59033869; called by muse, mutect2
- OR5F1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV53548289; called by muse, mutect2, varscan2
- OR5V1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs757315888, COSV65826634, COSV65829353; called by muse, mutect2, varscan2
- OR6K6 | c.362C>T p.S121F (on ENST00000368144; = p.S97F on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1160920320; called by muse, mutect2
- OR7D2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV100713018; called by muse, mutect2
- OR8K5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57890146; called by muse, mutect2
- OSMR | c.2882C>T p.T961I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs752350312; called by muse, mutect2, varscan2
- OTOF | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778939007, COSV55499924; called by muse, mutect2, varscan2
- PAFAH2 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs373547307; called by muse, mutect2
- PAK5 | c.1486G>C p.V496L | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV99058924; called by muse, mutect2
- PAX7 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV64751017; called by muse, mutect2
- PCDH10 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as rs942727116; called by muse, varscan2
- PCDH15 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.456); catalogued as COSV57275583; called by muse, mutect2, varscan2
- PCDH15 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs974331761; called by muse, mutect2
- PCDHA11 | c.1008G>A p.W336* | Nonsense Mutation (SNP) | VAF 24/235 reads (10%) | catalogued as rs112749867; called by muse, mutect2
- PCDHA8 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 86/846 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); catalogued as COSV100969986; called by muse, mutect2
- PCDHA8 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 83/837 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV65327436, COSV65328954; called by muse, mutect2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 67/549 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCDHB1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782121054; called by muse, mutect2, varscan2
- PCDHB16 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782137635, COSV53360115; called by muse, mutect2, varscan2
- PCDHB6 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1475662482; called by muse, mutect2
- PCDHGB2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as rs1214770155; called by muse, mutect2
- PDE8B | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767937257, COSV53732829; called by muse, mutect2, varscan2
- PFAS | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs570020614; called by muse, mutect2
- PHYH | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 65/500 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM001291, COSV53816428; called by muse, mutect2, varscan2
- PIK3CD | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 75/539 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1384520389, COSV63129074; called by muse, mutect2, varscan2
- PIP5K1A | c.836C>T p.P279L (on ENST00000368888 / NM_001135638.2; = p.P266L on NM_003557.3) | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1352387736; called by muse, mutect2
- PITPNM2 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99758697; called by muse, mutect2, varscan2
- PKP2 | c.2578-1G>A p.X860_splice | Splice Site (SNP) | VAF 17/301 reads (6%) | catalogued as COSV99297114; called by muse, mutect2
- PLA2G7 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV51258473; called by muse, mutect2
- PLCB2 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV53031444; called by muse, mutect2
- PLCE1 | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778433836, COSV99597664; called by muse, mutect2
- PLEC | c.3803C>T p.S1268F (on ENST00000322810 / NM_201380.4; = p.S1158F on NM_000445.5) | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1257318291; called by muse, mutect2, varscan2
- PLEKHG4 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775644209, COSV58574670; called by muse, mutect2, varscan2
- PLEKHH1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV100232870; called by muse, mutect2, varscan2
- POLR1F | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55998862; called by muse, mutect2
- POLR2A | c.3568C>T p.Q1190* | Nonsense Mutation (SNP) | VAF 36/478 reads (8%) | catalogued as rs1567707537; called by muse, mutect2
- POLR3GL | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs374345321, COSV100996899; called by muse, mutect2
- POLR3GL | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553763629; called by muse, mutect2
- PPDPFL | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57460843; called by muse, mutect2, varscan2
- PRAMEF12 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs776079674, COSV63214656; called by muse, mutect2, varscan2
- PRAMEF15 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 68/1139 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1427126667; called by muse, mutect2
- PRB2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs770351255, COSV66982551; called by muse, varscan2
- PRKDC | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as COSV58041870; called by muse, mutect2, varscan2
- PRRC2C | c.4507G>C p.E1503Q (on ENST00000367742; = p.E1501Q on NM_015172.4) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901307; called by muse, mutect2, varscan2
- PSG7 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs532113687, COSV68447492; called by muse, mutect2
- PSMB5 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100557387; called by muse, mutect2
- PTGDS | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as rs1347372453; called by muse, mutect2, varscan2
- PTPN13 | c.4781C>T p.P1594L (on ENST00000411767 / NM_080683.3; = p.P1575L on NM_006264.3) | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773507414; called by muse, mutect2
- PTPRQ | c.4475G>A p.W1492* (on ENST00000616559; = p.W1450* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as rs985717064; called by muse, mutect2
- PXDNL | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1244267078; called by muse, mutect2
- RAB5IF | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs961307456; called by muse, mutect2
- RAP1GAP2 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99624708; called by muse, mutect2
- RARS1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51565024; called by muse, mutect2
- RCOR2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1396486077; called by muse, mutect2, varscan2
- RCOR2 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1271927098; called by muse, mutect2, varscan2
- RELN | c.6863C>T p.S2288F | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209019971, COSV100632809; called by muse, mutect2, varscan2
- RELN | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as COSV59024200; called by muse, mutect2
- RGPD4 | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV61744511; called by muse, mutect2
- RIC1 | c.1903C>G p.R635G | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.695); catalogued as COSV52604297, COSV52605234, COSV52614879; called by muse, mutect2, varscan2
- RMDN3 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs534995621; called by muse, mutect2
- RNF123 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs757051847; called by mutect2, varscan2
- ROCK1 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV67694721, COSV67695967; called by muse, mutect2, varscan2
- RP1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 62/580 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55114388; called by muse, mutect2, varscan2
- RP1L1 | c.5216G>A p.G1739E | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs761451502; called by muse, mutect2, varscan2
- RP1L1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66752446; called by muse, mutect2, varscan2
- RPH3AL | c.425G>C p.S142T | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs774597264; called by muse, mutect2
- RPL5 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV59873592; called by muse, mutect2, varscan2
- RUNX1 | c.79G>A p.E27K (on ENST00000344691 / NM_001001890.3; = p.E54K on NM_001754.5) | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55868660, COSV55892827; called by muse, mutect2, varscan2
- RUSC1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs373143054; called by muse, mutect2
- SALL1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764851; called by mutect2, varscan2
- SCARA5 | c.1153+5G>A | Splice Region (SNP) | VAF 22/330 reads (7%) | catalogued as COSV100108032; called by muse, mutect2
- SCARA5 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100108014; called by muse, mutect2
- SCN10A | c.2605C>T p.L869F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs1297726448, COSV101479301; called by muse, mutect2, varscan2
- SCN4A | c.3777G>A p.K1259= | Splice Region (SNP) | VAF 15/102 reads (15%) | catalogued as rs1156522495; called by muse, mutect2, varscan2
- SCUBE1 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745429822; called by muse, mutect2
- SEC14L5 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 39/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52036141; called by muse, mutect2, varscan2
- SEMA3E | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.922); catalogued as COSV57080102; called by muse, mutect2
- SEMA4C | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs1472936766, COSV100560906; called by muse, mutect2, varscan2
- SGCZ | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as rs1404321308; called by muse, mutect2, varscan2
- SH2B3 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs778004604, COSV57987942; called by muse, mutect2
- SH2D4A | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56121304, COSV56122403; called by muse, mutect2
- SHOX | c.494T>C p.F165S | Missense Mutation (SNP) | VAF 60/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM074530, COSV61861572; called by muse, mutect2, varscan2
- SIGLEC11 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs745759468, COSV68567534; called by mutect2, varscan2
- SIRPG | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99404076; called by muse, mutect2, varscan2
- SLC13A2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs781976085, COSV58992843; called by muse, mutect2
- SLC26A5 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV59705018; called by muse, mutect2
- SLC30A3 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV51984970; called by muse, mutect2
- SLC38A11 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58052679; called by muse, mutect2, varscan2
- SLC41A1 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 79/630 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900306; called by muse, mutect2, varscan2
- SLC5A5 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs149148486, COSV55833330; called by muse, mutect2, varscan2
- SLITRK3 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as rs1225579801; called by muse, mutect2
- SLITRK5 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs1394977295, COSV61522371; called by muse, mutect2
- SMG7 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV61629974; called by muse, mutect2, varscan2
- SMIM7 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 60/545 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.911); catalogued as rs752894428; called by muse, mutect2, varscan2
- SNTG2 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 20/217 reads (9%) | catalogued as COSV57972720; called by muse, mutect2
- SOHLH1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs558571915, COSV53680909; called by muse, mutect2
- SPANXN3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV65140682; called by muse, mutect2, varscan2
- SPATA24 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1022211411; called by muse, mutect2, varscan2
- SPATC1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs539876524; called by muse, mutect2, varscan2
- SPHKAP | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV60867674; called by muse, mutect2
- SPSB4 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs531056572; called by mutect2, varscan2
- SPTA1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63752900, COSV63755020; called by muse, mutect2, varscan2
- SPTBN4 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs893558417; called by muse, mutect2
- SRRM2 | c.8069C>T p.S2690F | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1328708893; called by muse, mutect2, varscan2
- STARD4 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV56968797; called by muse, varscan2
- STARD8 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs775555373, COSV52932520; called by muse, mutect2, varscan2
- STYXL2 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as rs545997985, COSV54801641; called by mutect2, varscan2
- SUPT6H | c.3236C>G p.S1079* | Nonsense Mutation (SNP) | VAF 41/465 reads (9%) | catalogued as COSV58926451; called by muse, mutect2
- SUSD5 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs375235575; called by muse, mutect2, varscan2
- SYBU | c.383C>T p.S128F (on ENST00000276646 / NM_001099754.2; = p.S127F on NM_017786.6) | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.584); catalogued as rs1226489744; called by muse, mutect2, varscan2
- SYT6 | c.778G>T p.D260Y (on ENST00000610222 / NM_001366225.1; = p.D175Y on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65775004; called by muse, mutect2, varscan2
- TACR3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1383571483, COSV59200138, COSV59209171; called by muse, mutect2
- TBCCD1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100111828, COSV58661978; called by muse, mutect2
- TCF4 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV61897169; called by muse, mutect2
- TECTA | c.4472G>A p.G1491D | Missense Mutation (SNP) | VAF 50/578 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755434423; called by muse, mutect2
- TERT | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57225245; called by muse, mutect2
- TESC | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs772630732, COSV58811987; called by muse, mutect2, varscan2
- TESMIN | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99663693; called by muse, mutect2
- TET2 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54432941; called by muse, mutect2, varscan2
- TET2 | c.4106C>T p.S1369L | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54403232, COSV54432791; called by muse, mutect2, varscan2
- TF | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433402159; called by muse, mutect2
- TFAP2D | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as COSV50412850; called by muse, mutect2
- TFAP2E | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1006487877; called by muse, mutect2, varscan2
- TG | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV55079991; called by muse, mutect2, varscan2
- THAP12 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52609315; called by mutect2, varscan2
- THEG | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199660099, COSV61074571; called by muse, mutect2
- TJP1 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045909375, COSV100632234; called by muse, mutect2
- TLN1 | c.5249C>T p.S1750F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59208970; called by muse, mutect2, varscan2
- TLX3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 60/585 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440254907; called by muse, mutect2, varscan2
- TMEM132D | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV70596931; called by muse, mutect2
- TMPRSS11B | c.240G>A p.K80= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60294440; called by muse, mutect2, varscan2
- TMPRSS6 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 60/565 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs1343030713; called by muse, mutect2, varscan2
- TMPRSS9 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV60226255; called by muse, mutect2, varscan2
- TMX1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs775236782, COSV63284855; called by mutect2, varscan2
- TNFRSF10B | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 75/686 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs761287157, COSV52392032; called by muse, mutect2, varscan2
- TNXB | c.5767C>T p.R1923C (on ENST00000647633; = p.R1676C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766097197, COSV64489154; called by muse, mutect2
- TOP3A | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 50/550 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.07); catalogued as rs772811336; called by muse, mutect2
- TPO | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61102321; called by muse, mutect2
- TRAPPC12 | c.1603+1G>A p.X535_splice | Splice Site (SNP) | VAF 16/191 reads (8%) | catalogued as rs1458301330; called by muse, mutect2
- TRHDE | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53847225; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1107C>T p.A369= | Splice Region (SNP) | VAF 64/575 reads (11%) | catalogued as rs749519178; called by muse, mutect2, varscan2
- TRIM45 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as rs267597949; called by muse, mutect2
- TRIM5 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.918); catalogued as rs200209793; called by muse, mutect2, varscan2
- TRPA1 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.438); catalogued as COSV51563807; called by muse, varscan2
- TSC2 | c.2967-8C>T | Splice Region (SNP) | VAF 44/389 reads (11%) | catalogued as rs1060504085; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSGA10IP | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73245208; called by muse, mutect2, varscan2
- TSPEAR | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV59966253; called by muse, mutect2
- TTLL9 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs762112900; called by muse, mutect2, varscan2
- TUSC3 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65885329; called by muse, mutect2, varscan2
- TXNDC15 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100613578; called by muse, mutect2
- UNC79 | c.1433C>T p.S478F (on ENST00000393151 / NM_001346218.2; = p.S301F on NM_020818.5) | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56408133; called by muse, mutect2
- UNC93A | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV57811174; called by muse, mutect2
- USH1C | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758424766; called by muse, mutect2, varscan2
- USP5 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs201872573; called by muse, mutect2
- VPS72 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs907898877; called by muse, mutect2
- VWF | c.7570C>T p.P2524S | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs1009015592; called by muse, mutect2
- VWF | c.6801C>T p.F2267= | Splice Region (SNP) | VAF 67/684 reads (10%) | catalogued as COSV54611709; called by muse, mutect2
- WT1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV60067406, COSV60081277; called by muse, mutect2, varscan2
- YBX3 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1407360097; called by muse, mutect2
- ZBTB7A | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1235232708; called by muse, mutect2, varscan2
- ZC3H12B | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1160280338, CM137523; called by mutect2, varscan2
- ZFHX4 | c.8641G>A p.D2881N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777674733, COSV50497271; called by mutect2, varscan2
- ZIM3 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV54142721; called by muse, mutect2
- ZNF304 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99988362; called by muse, mutect2, varscan2
- ZNF354C | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs753635301, COSV100203745; called by muse, mutect2, varscan2
- ZNF354C | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59607390; called by muse, mutect2, varscan2
- ZNF398 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV60066509; called by muse, varscan2
- ZNF438 | c.2246G>A p.G749E | Missense Mutation (SNP) | VAF 60/584 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs1203852171; called by muse, mutect2, varscan2
- ZNF45 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99524165; called by muse, mutect2, varscan2
- ZNF469 | c.8510C>T p.P2837L (on ENST00000437464; = p.P2865L on NM_001367624.2) | Missense Mutation (SNP) | VAF 76/918 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330767118; called by muse, mutect2
- ZNF469 | c.9161C>T p.A3054V (on ENST00000437464; = p.A3082V on NM_001367624.2) | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1015869921; ClinVar: uncertain significance; called by muse, mutect2
- ZNF606 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.1); catalogued as COSV58707793; called by muse, mutect2
- ZNF705A | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV100828312; called by muse, mutect2
- ZNF839 | c.1424C>T p.A475V (on ENST00000558850 / NM_001267827.1; = p.A591V on NM_018335.5) | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.631); catalogued as rs748004734; called by muse, mutect2, varscan2
- AARD | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA12 | c.1741G>A p.D581N (on ENST00000272895 / NM_173076.3; = p.D263N on NM_015657.3) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.3719A>C p.N1240T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ABCA2 | c.5960G>A p.G1987E (on ENST00000614293; = p.G1957E on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA8 | c.3044T>C p.L1015P | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCC9 | c.2429T>G p.I810S | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACSS3 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ACTB | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 59/599 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ACTN2 | c.1840-7C>T | Splice Region (SNP) | VAF 66/647 reads (10%) | called by muse, varscan2
- ADAMTS12 | c.3550G>A p.G1184R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS13 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 65/589 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ADAMTS17 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ADAMTS5 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 36/519 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- ADGRB3 | c.4091A>T p.E1364V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADSS2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGAP5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 82/767 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- AGBL2 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.348); called by muse, mutect2
- AHNAK | c.14473A>T p.I4825F | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- AHNAK2 | c.11144C>T p.A3715V | Missense Mutation (SNP) | VAF 61/648 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.042); called by muse, mutect2
- AKAP1 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- AL136295.1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.165); called by muse, mutect2
- ALDH1L1 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- ALDOC | c.325-8C>T | Splice Region (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- ALG9 | c.1511A>G p.E504G (on ENST00000614444 / NM_001352418.1; = p.E511G on NM_024740.2) | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AMOT | c.2882C>T p.P961L (on ENST00000371959 / NM_001113490.1; = p.P552L on NM_133265.3) | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, varscan2
- AMOTL1 | c.2746G>C p.G916R | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.091); called by muse, mutect2
- ANK2 | c.10498G>A p.E3500K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- ANKRD30B | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- ANKS1B | c.62A>T p.K21I | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AP3B2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.441); called by muse, mutect2
- APLNR | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOBR | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.078); called by muse, mutect2
- ARAP1 | c.1103C>G p.S368C (on ENST00000393609 / NM_001040118.2; = p.S123C on NM_015242.4) | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARF5 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ARFGEF3 | c.2026T>C p.F676L | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ARHGAP9 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARL13A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARX | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASIC4 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ASTN2 | c.3818T>G p.V1273G (on ENST00000313400 / NM_001365069.1; = p.V1222G on NM_014010.5) | Missense Mutation (SNP) | VAF 46/384 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ATG2A | c.2833-1G>A p.X945_splice | Splice Site (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- ATG7 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP10A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHD1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHD1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BAIAP2L2 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- BCAM | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- BDP1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); called by muse, mutect2
- BICDL2 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- BIN3 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- BMP3 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPIFC | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BRWD1 | c.4235A>T p.E1412V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- BSG | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 74/558 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- C10orf90 | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- C11orf49 | c.366G>A p.R122= | Splice Region (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- C3orf20 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- C9orf152 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- CACNA1A | c.1304A>G p.N435S | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CACNA1E | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1H | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CARMIL1 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CASKIN2 | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASP8 | c.1186G>A p.E396K (on ENST00000432109 / NM_033355.3; = p.E413K on NM_001228.4) | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.303); called by muse, varscan2
- CATSPERZ | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CBR3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); called by mutect2, varscan2
- CCDC116 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.2891T>C p.V964A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, varscan2
- CCDC171 | c.3395C>G p.A1132G | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CCDC191 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- CCDC88A | c.5441G>A p.G1814E (on ENST00000436346 / NM_001365480.1; = p.G1786E on NM_018084.5) | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CD101 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.185); called by muse, mutect2
- CD163 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR3 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- CDK18 | c.1311G>A p.L437= (on ENST00000506784 / NM_212503.3; = p.L407= on NM_002596.4) | Splice Region (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- CENPE | c.5649A>C p.E1883D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP83 | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CERK | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CES2 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CFAP97 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CGB8 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 21/397 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- CHDH | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 68/634 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHRD | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHRFAM7A | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- CHRNA7 | c.1121T>A p.V374E | Missense Mutation (SNP) | VAF 78/1441 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.062); called by muse, mutect2
- CLDN16 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CLPSL2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMIP | c.1052G>A p.S351N (on ENST00000537098 / NM_198390.2; = p.S257N on NM_030629.3) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CNN2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- CNTROB | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COG8 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL19A1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- COL19A1 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- COL6A3 | c.8207T>G p.L2736R | Missense Mutation (SNP) | VAF 62/567 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COLQ | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPT1B | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CRB1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- CRMP1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- CSE1L | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- CSF2RB | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 43/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CTCFL | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- CYP2R1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DACT3 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- DBX2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- DEPDC5 | c.3264-5C>T | Splice Region (SNP) | VAF 47/570 reads (8%) | called by muse, mutect2
- DGAT2 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGCR8 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKD | c.747C>A p.C249* (on ENST00000264057 / NM_152879.3; = p.C205* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/329 reads (10%) | called by muse, mutect2, varscan2
- DGKG | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DGKH | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2
- DGKZ | c.1066-6C>T | Splice Region (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- DHCR7 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 37/528 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- DHRS12 | c.814G>A p.A272T (on ENST00000444610 / NM_001377930.1; = p.A223T on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- DHX37 | c.3236C>T p.S1079L | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- DISC1 | c.1368C>G p.D456E | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2
- DLGAP3 | c.2008A>G p.R670G | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- DNAAF1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- DNAJC13 | c.3811C>T p.P1271S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- DSCAM | c.3212G>A p.G1071D | Missense Mutation (SNP) | VAF 31/341 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- EBF1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EDNRA | c.900+1G>A p.X300_splice | Splice Site (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- EEPD1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 38/433 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- EFR3B | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EIF4G2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ENG | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- ENTPD2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPO | c.160-1G>A p.X54_splice | Splice Site (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- ERO1B | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.223); called by muse, mutect2
- ERVV-2 | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- ESRP2 | c.1883G>A p.G628E (on ENST00000565858 / NM_001365264.1; = p.G618E on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ESRRG | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- EXD3 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 68/672 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.069); called by muse, mutect2
- EYA3 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FA2H | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 83/711 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM118A | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 70/584 reads (12%) | called by muse, mutect2, varscan2
- FAM13C | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM47C | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 59/300 reads (20%) | called by muse, varscan2
- FAM83H | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT4 | c.5992G>A p.G1998S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBN3 | c.5603A>G p.Y1868C | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FBXL19 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2
- FGF21 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 52/489 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FLNC | c.7606G>A p.G2536R | Missense Mutation (SNP) | VAF 50/519 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FLT3LG | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- FRAS1 | c.8776G>A p.D2926N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2
- FRAS1 | c.10052T>C p.M3351T | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABPB2 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALK1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAS2L2 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GEMIN7 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GFI1B | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 102/799 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GIMAP6 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GJA9 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, varscan2
- GLP1R | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- GLRA1 | c.54C>T p.F18= | Splice Region (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- GNAT2 | c.445A>C p.N149H | Missense Mutation (SNP) | VAF 79/514 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPRIN1 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2
- H1-7 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- HCAR1 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HECW1 | c.3438G>A p.R1146= | Splice Region (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- HELZ | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- HIVEP1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- HIVEP2 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- HLA-A | c.343+5_343+33del | Splice Region (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel
- HMCN2 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HOOK2 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA8 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- HSPB9 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 73/715 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HTR1F | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HTR3D | c.257+2T>G p.X86_splice (on ENST00000382489 / NM_001163646.2; = p.V29G on NM_001145143.1) | Splice Site (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- HYOU1 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HYOU1 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV2D-30 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 29/415 reads (7%) | called by muse, mutect2
- IGSF21 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- IL18R1 | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ING3 | c.605T>G p.V202G | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- INSR | c.3659+2T>G p.X1220_splice | Splice Site (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- IPO8 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- IQCH | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAZF1 | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- JPT2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCNC2 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KCNMA1 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- KCNMA1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, varscan2
- KIAA1549L | c.1496G>A p.G499E (on ENST00000321505; = p.G796E on NM_012194.3) | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KIF16B | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); called by muse, mutect2
- KIR2DS4 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- KLHDC4 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 51/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHDC7B | c.82G>A p.G28S (on ENST00000395676; = p.G669S on NM_138433.5) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KNDC1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KRTAP17-1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 29/234 reads (12%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP24-1 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LAMA4 | c.3495G>C p.K1165N (on ENST00000230538 / NM_001105206.3; = p.K1158N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- LAMA4 | c.2570C>T p.A857V (on ENST00000230538 / NM_001105206.3; = p.A850V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- LARGE1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCOR | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LCOR | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- LEXM | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 45/386 reads (12%) | called by muse, mutect2, varscan2
- LGI1 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- LIPE | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- LMNA | c.1969-7C>G | Splice Region (SNP) | VAF 47/451 reads (10%) | called by muse, mutect2, varscan2
- LRP4 | c.4135G>A p.V1379I | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- LRRC7 | c.2659C>A p.P887T (on ENST00000651989 / NM_001370785.2; = p.P854T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK2 | c.4022G>A p.G1341E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAGI2 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- MAP2 | c.3632C>T p.S1211F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MAP2 | c.4442C>T p.P1481L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- MAP7D1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.683); called by muse, mutect2
- MAP7D1 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAPK10 | c.646G>A p.G216R (on ENST00000359221 / NM_001351625.2; = p.G254R on NM_002753.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MCM3AP | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEIS3 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- MELTF | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MERTK | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 46/744 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2
- MICALL1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MKI67 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2
- MKI67 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2
- MLLT10 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MLLT3 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MMACHC | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MMEL1 | c.1904G>T p.W635L | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP20 | c.812-1G>A p.X271_splice | Splice Site (SNP) | VAF 51/405 reads (13%) | called by muse, mutect2, varscan2
- MPEG1 | c.1789A>C p.T597P | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- MPHOSPH8 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MRTFB | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MS4A6A | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- MSANTD4 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); called by muse, varscan2
- MTA2 | c.190+1G>T p.X64_splice | Splice Site (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- MTF2 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- MUC16 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MUC22 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0); called by muse, mutect2
- MUC5B | c.11903G>A p.G3968E | Missense Mutation (SNP) | VAF 40/501 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- MUC6 | c.4261C>T p.P1421S | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.132); called by muse, varscan2
- MXRA5 | c.319-1G>A p.X107_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- MYH7 | c.1067T>A p.I356N | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- MYLK2 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NAT10 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NBPF9 | c.2158G>A p.G720S | Missense Mutation (SNP) | VAF 49/544 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.037); called by muse, mutect2
- NEK6 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEU4 | c.977G>A p.G326E (on ENST00000391969 / NM_001167602.3; = p.G338E on NM_080741.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHLRC2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- NISCH | c.3881C>T p.S1294F | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NKX2-1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 49/501 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, varscan2
- NLGN1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP12 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 60/688 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOTCH3 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPDC1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NRK | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NSUN4 | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- NT5E | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 63/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NTRK3 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NWD2 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- NXN | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2
- NXPE2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OASL | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- OR14J1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1N2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OR2T4 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2
- OR51A4 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- OR5M10 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR8G2P | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2
- OSCP1 | c.719C>A p.A240E (on ENST00000356637 / NM_001330493.1; = p.A230E on NM_145047.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OXSR1 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- P2RY8 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPN1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.636); called by muse, mutect2
- PALD1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAPPA2 | c.1910A>G p.N637S | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.09); called by muse, mutect2
- PARD3B | c.2761G>A p.E921K (on ENST00000406610 / NM_001302769.2; = p.E852K on NM_057177.7) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PAX8 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDH9 | c.3668A>G p.K1223R (on ENST00000377865 / NM_203487.3; = p.K1189R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- PCDHA12 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 88/780 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PCDHA2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PCDHA9 | c.2390G>A p.G797E | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- PCDHAC1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PCDHB15 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHB6 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2
- PCDHGB3 | c.2303T>G p.L768R | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2
- PCSK5 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDZD7 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 60/650 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PENK | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2
- PEPD | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 62/686 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PER2 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- PEX14 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PHETA2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- PHETA2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- PHIP | c.5282G>A p.G1761D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHRF1 | c.1891T>C p.W631R (on ENST00000264555 / NM_001286581.2; = p.W630R on NM_020901.4) | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIF1 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIKFYVE | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, mutect2
- PITPNA | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.3908G>A p.G1303E | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PKD1L2 | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.104); called by muse, mutect2
- PKHD1 | c.8488C>T p.L2830F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKHD1L1 | c.8336A>T p.Y2779F | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PKN2 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.542); called by muse, mutect2
- PLAGL1 | c.141T>A p.Y47* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- PLCG2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2
- PLCH1 | c.1249G>A p.D417N (on ENST00000340059 / NM_001130960.2; = p.D429N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2
- PLEC | c.12859A>G p.K4287E (on ENST00000322810 / NM_201380.4; = p.K4177E on NM_000445.5) | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.285); called by muse, mutect2
- PLEC | c.11045G>A p.G3682E (on ENST00000322810 / NM_201380.4; = p.G3572E on NM_000445.5) | Missense Mutation (SNP) | VAF 93/831 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLIN4 | c.1613G>A p.G538E (on ENST00000301286; = p.G553E on NM_001367868.2) | Missense Mutation (SNP) | VAF 48/474 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PLIN4 | c.1382G>A p.G461D (on ENST00000301286; = p.G476D on NM_001367868.2) | Missense Mutation (SNP) | VAF 62/626 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLIN5 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLXDC2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, mutect2
- PLXNA1 | c.4363-6C>T | Splice Region (SNP) | VAF 74/649 reads (11%) | called by muse, mutect2, varscan2
- POLE | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRICKLE1 | c.2476A>G p.K826E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PRKCH | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PRL | c.682T>G p.*228Eext*9 | Nonstop Mutation (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- PROKR1 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- PRPF4B | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRRT3 | c.2748G>A p.W916* | Nonsense Mutation (SNP) | VAF 25/229 reads (11%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8417C>T p.P2806L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PSG4 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2
- PTPN13 | c.4780C>T p.P1594S (on ENST00000411767 / NM_080683.3; = p.P1575S on NM_006264.3) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRD | c.5681A>C p.Q1894P | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PTPRN | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PYGL | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- QPCTL | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- RAB2B | c.432A>G p.I144M | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by muse, mutect2
- RALGAPA1 | c.2267-2A>T p.X756_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- RBM12B | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBMS2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- RBMXL3 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RBMXL3 | c.1748A>G p.N583S | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
783 further variants in this file (126 protein-altering or splice-affecting, 463 silent, 194 other) are not listed here.
